Gene-level copy-number profile of specimen HCM-CSHL-0142-C18-85A from HCMI case HCM-CSHL-0142-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: GB; Age at diagnosis: 61.3 years (22,391 days).
Specimen HCM-CSHL-0142-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7b3a0da1-3b56-411d-98e9-4c2347ba8e93.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0142-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/d5282020-3240-49a2-931e-31135dc4d79e

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 980; copy number 2: 4,057; copy number 3: 9,411; copy number 4: 19,197; copy number 5: 17,117; copy number 6: 4,160; copy number 7: 858; copy number 8: 1,220; copy number 9: 326; copy number 10: 1,510; copy number 12: 59; copy number 17: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 61 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,498,785–143,500,512, 2 genes, copy number 17: AC239859.2, LINC02799.
- chr1:143,905,487–144,068,350, 4 genes, copy number 12 (within-gene range 7–12): AC246680.1, RPL22P5, FAM72C, SRGAP2D.
- chr8:28,890,395–31,033,715, 55 genes, copy number 12: HMBOX1, Metazoa_SRP, HMBOX1-IT1, RNA5SP260, AC108449.2, KIF13B, AC108449.3, AC108449.1, HMGB1P23, DUSP4, AC084262.2, AC084262.1, AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099, AC131254.1, AC131254.3, AC131254.2, LINC02209, MIR3148, MAP2K1P1, RNU6-1218P, SARAF, AC044849.1, LEPROTL1, RPS15AP24, MBOAT4, AC026979.2, DCTN6, AC026979.1, AC026979.4, AC026979.3, HSPA8P11, AC090820.1, AC109329.1, PPIAP84, TUBBP1, RBPMS-AS1, RBPMS, AC102945.2, GTF2E2, AC102945.1, SMIM18, RNU5A-3P, GSR, UBXN8, HIKESHIP3, PPP2CB, TEX15, AC090281.1, AC008066.1, PURG.

Autosomal genes at a single copy (total copy number 1): 542. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
